CPTAC case C3N-01383 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/48737b20-3e04-490b-9b39-921bf2c09e52

Demographics
Sex at birth: female; Race: white; Year of birth: 1936; Vital status: Dead; Days to death: 791 days (2.2 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 80.5 years (29,417 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 791 days (2.2 years); Progression or recurrence: yes; Days to recurrence: 477 days (1.3 years); Days to last follow up: 791 days (2.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm; Lymph node involvement: Positive; Lymph nodes positive: 7; Lymph nodes tested: 12; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (3 entries)
- Days to follow up: 385 days (1.1 years); Disease response: Progressive Disease; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 667 days (1.8 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 477 days (1.3 years); Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 791 days (2.2 years); Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 90 kg; Height: 168 cm; BMI: 31.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 60; Cigarettes per day: 30; Tobacco smoking onset year: 1956; Tobacco smoking quit year: 1996; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 40.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01383-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -14 days; Initial weight: 173 mg; Time between excision and freezing: 16 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01383-21: Section location: Head; Percent tumor nuclei: 40; Percent necrosis: 1.
- Sample C3N-01383-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -14 days; Initial weight: 157 mg; Time between excision and freezing: 16 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01383-23: Section location: Head; Percent tumor nuclei: 40; Percent necrosis: 2.
- Sample C3N-01383-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -13 days; Method of sample procurement: Blood Draw.
